Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3B6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3B6-01A (Primary Tumor).

[page 1 of 3]
Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- A. Right pelvic lymph nodes; dissection:
- Five lymph nodes, no tumor (0/5).
- B. Left pelvic lymph nodes, dissection:
- Ten lymph nodes, no tumor (0/10).
- C. Left distal ureter; excision:
- Segment of ureter, no tumor.
- D. Bladder, prostate, seminal vesicles, and vas deferens, cystoprostatectomy:
- Invasive high grade papillary urothelial carcinoma with poorly differentiated pleomorphic areas and focal glandular differentiation, see pathologic parameters.
- Adenocarcinoma of the prostate, see pathologic parameters.
- E. Right distal ureter; excision:
- Segment of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive papillary urothelial carcinoma with poorly differentiated pleomorphic areas and focal glandular differentiation.
2. Grade of tumor: High grade.
3. Depth of invasion: Muscularis propria, outer half.
4. Tumor distribution: Multifocal (4.1 cm largest size) at right lateral wall and posterior wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/15).
9. pTNM: pT2b,N0,MX

Effective --- this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 3+3=6.
2. Perineural Invasion: Present.
3. Tumor Location: Peripheral zone - right and left.
4. Tumor Volume Estimate: 5%.
5. High-grade P.I.N.: Multifocal
6. Seminal Vesicles: Negative for tumor.
7. Extraprostatic extension: Absent.
8. Peripheral Margin: Negative for tumor.
9. Distal (apical) Margin: Negative for tumor.
10. Proximal (basilar) Margin: Negative for tumor.
11. Regional Lymph Nodes: Negative for tumor (0/15).
12. pTNM: pT2c,N0,MX.

Effective () this Checklist utilizes the 7th edition TNM staging
Page 1

Dual/Sync'ronous Primary Noted		X

[page 2 of 3]
system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx

[], MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D., Ph.D.

Electronically Signed Out by [], MD

Clinical History:

The patient is a -year-old male with invasive high grade papillary urothelial carcinoma undergoing cystoprostatectomy.

Specimens Received:

A: Right pelvic lymph nodes

B: Left pelvic lymph nodes

C: Left distal ureter

D: Bladder, prostate, seminal vesicles, and vas deferens

E: Right distal ureter

Gross Description:

The specimens are received in 5 containers, each labeled the patient's name and medical record number.

Part A. is further designated "1. Right pelvic lymph nodes". It is a 4.5 by 2 x 2 centimeter aggregate of lobulated yellow tan tissue. Dissection for lymph nodes reveals multiple lymph node candidates ranging from 0.8-4.5 cm in greatest diameter. Specimen is entirely submitted as follows:

A1 and A2: 2 lymph node candidates each

A3 and A4: 1 lymph node candidate, bisected

A5-A8: One lymph node candidate, sectioned

Part B. is further designated "2. Left pelvic lymph nodes". Received fresh and placed in formalin is a 5 x 3 x 2 cm aggregate of lobulated yellow-tan fibroadipose tissue. Sectioning for lymph nodes reveals multiple lymph node candidates ranging from 0.6-3.2 cm in greatest diameter. The lymph nodes are entirely submitted as follows:

B1: 3 lymph node candidates

B2: 4 lymph node candidates

B3: 1 lymph node candidate, sectioned

B4: One lymph node candidate, sectioned

B5-B6: One lymph node candidate, bisected

B7-B8: one lymph node candidate, bisected

Part C. is further designated "3. Left distal ureter". Received fresh and placed in formalin is an unoriented portion of ureter which is 0.9 cm long and 0.4 cm in diameter. The specimen is bisected and entirely submitted in C1.

Part D. is further designated "4. Bladder, prostate, seminal vesicles, vas deferens". Received fresh and placed in formalin is a 338.5 g, 18.9 x 9.1 x 3.0 cm cystoprostatectomy specimen consisting of a 9.5 x 8.5 x 3.3 cm bladder with attached mesenteric fat and a 5.5 x 5.5 x 3.7 cm prostate. The right seminal vesicles measure 3.5 x 1.1 x 1.0 cm and right vas deferens measures 8 cm. The left seminal vesicles measures 3.5 x 1.2 x 0.5 cm and left vas deferens measures 6 cm. The right ureteral stump measures 1.4 cm, the left measures 2.3 cm, and both demonstrate intact, patent lumens.

The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin, intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with with a 0.8 cm area of induration on the right side in the third and fourth slices from the apex.

[page 3 of 3]
There is a 0.4 cm area of induration on the left in the seventh slice from apex. The opened bladder reveals a 4.1 x 2.5 x 1.0 cm red-brown, hemorrhagic, papillary, friable mass located in the right posterior wall extending laterally. On cut section, the mass extends into the muscularis propria and into the perivesicular fat. There is a 2.2 x 1.1 x 2 cm area of firm white-tan induration the perivesicular fat from the posterior to the dome. It comes within 0.1 cm of the inked margin. The mucosa surrounding the mass is wrinkled pink-tan and grossly unremarkable with a uniform 0.7 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent.

Representative sections are submitted as follows:

- D1: Distal prostatic urethral margin (apex)
- D2: Right ureter resection margin
- D3: Left ureter resection margin
- D4-D5: Apical prostate margin
- D6-D9: Bladder mass/Ulceration in posterior wall
- D10: Uninvolved bladder mucosa bladder dome
- D11: Uninvolved bladder mucosa anterior wall
- D12: Uninvolved bladder mucosa left
- D13-D14: Right wall, bisected
- D15: Trigone
- D16 -D28: Representative right lobe of prostate from apex to base
- D29-D36: Representative left lobe of prostate submitted from apex to base
- D37: Right vas deferens and seminal vesicles
- D38: Left seminal vesicle and vas deferens
- D39-43: Remainder of large polypoid mass

Part E is further designated "5. Right distal ureter". Received fresh and placed in formalin is a 2.4 cm long by 0.4 portion of ureter. There is a clear stitch at one end which is not designated. The end opposite the stitch is inked blue. Each end of the ureter is shaved and submitted in E1.

XX
[] M.D.

Source: NCI Genomic Data Commons file 334837c1-c7cc-4a32-96c6-d6e6650447b1 (TCGA-FD-A3B6.7FC255AC-F494-49EB-B90A-A43409E15CD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).